Somatic mutation profile of tumor specimen TCGA-SR-A6MV-01A (aliquot TCGA-SR-A6MV-01A-11D-A35I-08) from TCGA case TCGA-SR-A6MV, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Paraganglioma, malignant; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 35.8 years (13,074 days).
Specimen TCGA-SR-A6MV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58f893c8-1e7b-4ade-b438-63683e6f2abf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SR-A6MV-10D (Blood Derived Normal), aliquot TCGA-SR-A6MV-10D-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b806a79-7a7b-4e20-985b-5545b92a03cb

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Splice Site 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPAS1 | c.1595A>G p.Y532C | Missense Mutation (SNP) | VAF 80/90 reads (89%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55383831, COSV55385520; called by muse, mutect2, varscan2
- ARSI | c.995C>A p.P332H | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1369101814; called by muse, mutect2, varscan2
- COL19A1 | c.1680+1G>A p.X560_splice | Splice Site (SNP) | VAF 45/111 reads (41%) | catalogued as rs1296850746; called by muse, mutect2, varscan2
- EHBP1 | c.3034G>A p.V1012I | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV99860359; called by muse, mutect2, varscan2
- ARNTL | c.1617+1G>A p.X539_splice (on ENST00000403290 / NM_001297719.2; = p.X538_splice on NM_001178.5 and 4 other RefSeq transcripts) | Splice Site (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- EPS8 | c.1439C>G p.S480C | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- CUX1 | c.36A>G p.E12= (on ENST00000292535 / NM_181552.4; = p.E23= on NM_001913.5) | Silent (SNP) | VAF 10/154 reads (6%) | called by muse, mutect2
